Gene-level copy-number profile of tumor specimen TCGA-XF-AAMF-01A from TCGA case TCGA-XF-AAMF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 68.5 years (25,023 days).
Specimen TCGA-XF-AAMF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a6ec7f58-b1bf-43be-8860-17a5fda8aa54.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-AAMF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/78e1b62e-a6bb-4cbe-b9e9-963dbdfd3ce5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 17,115; copy number 2: 33,067; copy number 3: 7,770; copy number 4: 1,291; copy number 5: 316; copy number 6: 127; copy number 7: 21; copy number 10: 20; copy number 11: 70; copy number 14: 16; copy number 20: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-AAMF-01A-21D-A42D-01): tumor purity 0.72, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 574 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:39,293,228–39,908,300, 7 genes, copy number 6 (within-gene range 1–6): KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40.
- chr12:39,819,750–39,819,883, 1 gene, copy number 6: AC121336.1.
- chr12:41,698,495–42,590,355, 21 genes, copy number 7 (within-gene range 4–7): MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3.
- chr12:43,718,992–45,216,041, 20 genes, copy number 5: PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1.
- chr12:45,729,706–45,908,040, 1 gene, copy number 5 (within-gene range 1–5): ARID2.
- chr12:45,874,035–47,236,662, 22 genes, copy number 5 (within-gene range 1–5): RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1.
- chr16:46,469,341–53,052,873, 158 genes, copy number 5–20 (broad region; genes not listed).
- chr20:31,257,664–34,311,802, 119 genes, copy number 6 (broad region; genes not listed).
- chr20:44,106,590–50,963,929, 225 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,694. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
